Surgical pathology report (de-identified scan), TCGA case TCGA-CV-A460, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-A460-01A (Primary Tumor).

[page 1 of 2]
DOB:

Sex: M

Physician:

Accession:

Received:

Pathologist

Case type: Surgical History

** Case Imported from legacy computer system. The format of this report does not match the original case. **
** For cases prior to , the section "SPECIMEN" may have been added. **

DIAGNOSIS

(A) LYMPH NODE, LEFT EXTERNAL JUGULAR, EXCISION:

Two lymph nodes, no tumor present.

(B) LARYNX, TOTAL LARYNGECTOMY, PARTIAL PHARYNGECTOMY AND BILATERAL NECK
DISSECTION WITH SUBTOTAL THYROIDECTOMY:

INVASIVE POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA OF THE RIGHT
PYRIFORM SINUS. SURGICAL MARGINS ARE FREE OF TUMOR.

Submental lymph node, 1 lymph node, no tumor present.

Right Level I, 4 lymph nodes, no tumor present (0/4).

Right level II, METASTATIC SQUAMOUS CELL CARCINOMA IN 3 OF 3 LYMPH
NODES WITH EXTRACAPSULAR EXTENSION (3/3).

Right Level III, 9 lymph nodes, no tumor present (0/9).

Right Level IV, METASTATIC SQUAMOUS CELL CARCINOMA IN 1 OF 22 LYMPH
NODES WITH EXTRACAPSULAR EXTENSION (1/22).

Left Level III, 15 lymph nodes, no tumor present (0/15).

Left Level IV, 20 lymph nodes, no tumor present (0/20).

Left level V, 4 lymph nodes, no tumor present (0/4).

Salivary gland, unremarkable.

Thyroid gland, unremarkable.

(C) TEETH, EXTRACTION:

For gross examination only.

1cd-0-3

Carcinoma, squamous cell, nos 8070/3
Site: larynx, nos c32.9

W
10/1/12

Entire report and diagnosis completed by:
Report released by:

GROSS DESCRIPTION

(A) LEFT EXTERNAL JUGULAR LYMPH NODE - Fibroadipose tissue, 3.0 x 2.0 x 1.0
cm containing two lymph nodes, 1.5 and 1.0 cm in greatest dimension. The
larger lymph node exhibits near that complete fat replacement. The smaller
lymph node contains a dark tan/red nodule. Entirely submitted for frozen
section examination.

SECTION CODE: A1-A2, frozen section examination.

(B) TOTAL LARYNGECTOMY, PARTIAL PHARYNGECTOMY AND BILATERAL NECK DISSECTION
AND SUBTOTAL THYROIDECTOMY - A total laryngectomy and bilateral neck
dissection of thyroidectomy (9.0 x 9.0 x 4.0 cm). Multiple enlarged lymph
nodes were noted on the right side. On the laryngectomy specimen, a 2.0 x 1.0
x 1.0 cm ulcerated and contracted mass is noted in the right pyriform sinus.
Tumor does not encroach on the right side of the larynx and is confined to the
right pyriform area. No other noticeable lesion is noted in the right or left
transglottic or subglottic areas. Tumor submitted sequentially.

SECTION CODE: B1-B13, mucosal margins of resection; B14-B21, sequential

[page 2 of 2]
DOB:

Sex: M

Physician:

Received:

Pathologist:

Accession:

Case type: Surgical History

sectioning of the tumor from right to left; B22, right transglottic mucosa; B23, B24, left transglottic mucosa; B25, representative sections of thyroid; B26, submental lymph node; B27, level I, right, one lymph node bisected; B28, level I, right, one lymph node bisected; B29, level I, right, one lymph node bisected; B30, level I, right, one lymph node bisected; B31, level I, right, submandibular gland; B32, level II, right, grossly involved lymph node representative section; B33, level II, right, one lymph node bisected; B34, level II, right, one lymph node bisected; B35-B37, level III, right, multiple lymph nodes; B38, level IV, right, grossly involved lymph node, representative section; B39, level IV, right, one lymph node bisected; B40, level IV, right, four lymph nodes; B41, level IV, right, multiple lymph nodes; B42, level IV, right, five lymph nodes; B43, level IV, right, three lymph nodes; B44-B47, level II, left, multiple lymph nodes; B44, level III, left, three lymph nodes; B45, level III, left, multiple lymph nodes; B46, level III, left, four lymph nodes; B47, level III, left, three lymph nodes; B48, level III, left, one lymph node bisected; B49, level III, left, three lymph nodes; B50, level III, left, two lymph nodes; B51, level III, left, four lymph nodes; B52, level IV, left, multiple lymph nodes; B53, level IV, left, two lymph nodes; B54, level IV, left, two lymph nodes; B55, level IV, left, two lymph nodes; B56, level IV, left, multiple lymph nodes; B57, level IV, left, four lymph nodes; B58, level IV, left, multiple lymph nodes; B59, level V, left, three lymph nodes; B60, level V, left, two lymph nodes; B61, level V, left, one lymph node trisected.

*FS/DX: CIRCUMFERENTIAL MUCOSAL MARGINS, NO TUMOR PRESENT.

(C) TEETH - Three teeth with multiple fragments of dental material. One tooth has a silver-colored crown. No sections obtained.

SNOMED CODES

M-80703 M-80706 T-24100 T-B6000 T-C4200

HI/PA Discrepancy		☒

Page 2 of 2

History Case Pathology Report
File under: Pathology

History Case Pathology

Source: NCI Genomic Data Commons file bc9e9ad5-1680-4559-99d4-e4c46eca61f1 (TCGA-CV-A460.0779E47B-5351-4169-9F9F-D51D77EA108D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).